Somatic mutation profile of tumor specimen C3L-06352-55 (aliquot CPT0323600002) from CPTAC case C3L-06352, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 67.7 years (24,717 days).
Specimen C3L-06352-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccd528f8-3e2c-4e3e-8a72-757ef636c28c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06352-50 (Buccal Cell Normal), aliquot CPT0323570003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e5c903c-52af-4e3e-9a86-1756e9089855

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX38 | c.3271G>A p.V1091M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1398815604; called by muse, mutect2, varscan2
- KLHL31 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs202179716; called by muse, mutect2, varscan2
- NOS1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs1182847393; called by muse, mutect2
- CWF19L1 | c.872T>A p.F291Y | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MLIP | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NYNRIN | c.5669del p.P1890Rfs*48 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- ADGRA2 | c.3984G>A p.K1328= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as rs1432465226; called by muse, mutect2
- RARA | c.179-6915_179-6912del | Intron (DEL) | VAF 32/83 reads (39%) | called by mutect2, pindel, varscan2
- SRL | c.62-2313G>A | Intron (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
